Somatic mutation profile of tumor specimen TCGA-VS-A952-01A (aliquot TCGA-VS-A952-01A-11D-A387-09) from TCGA case TCGA-VS-A952, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 66.7 years (24,345 days).
Specimen TCGA-VS-A952-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eaa6787e-65f3-4d9d-b6e4-85f7086911ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A952-10A (Blood Derived Normal), aliquot TCGA-VS-A952-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4178d9c3-7918-4cb7-b856-bbf1dea88311

The open-access MAF lists 138 somatic variants for this specimen: 94 protein-altering or splice-affecting, 39 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 39, Nonsense Mutation 8, Frame Shift Del 4, RNA 2, Splice Site 2, 5'Flank 2, Frame Shift Ins 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 64/80 reads (80%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121909218, CM115947, CM971272, COSV64289566, COSV64291659; ClinVar: pathogenic; called by muse, varscan2
- SMAD4 | c.1058A>G p.Y353C | Missense Mutation (SNP) | VAF 11/55 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs377767346, CM994757, COSV61688013; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- A2ML1 | c.361G>A p.G121S | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.251); catalogued as rs768048394, COSV100229200, COSV55299790; called by muse, mutect2, varscan2
- ACLY | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs781941291, COSV61250569; called by muse, mutect2, varscan2
- AIFM3 | c.1396G>A p.G466S | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99302066; called by muse, mutect2, varscan2
- AKAP3 | c.1826G>A p.R609H | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs148718105, COSV57413438; called by muse, mutect2, varscan2
- AMPH | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768583906, COSV57761502; called by muse, mutect2, varscan2
- ARHGAP12 | c.1297G>T p.E433* | Nonsense Mutation (SNP) | VAF 56/145 reads (39%) | catalogued as COSV100260723; called by muse, mutect2, varscan2
- ATN1 | c.1314G>A p.W438* | Nonsense Mutation (SNP) | VAF 33/67 reads (49%) | catalogued as COSV100755883; called by muse, mutect2, varscan2
- ATP2B3 | c.2732G>A p.R911Q | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1160033001, COSV99685224; called by muse, mutect2, varscan2
- BTNL3 | c.998C>A p.S333Y | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV61565793; called by muse, mutect2, varscan2
- CACNB3 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.04); catalogued as rs953272297, COSV99975009; called by muse, mutect2, varscan2
- CCDC97 | c.975G>T p.R325S | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.198); catalogued as COSV99523799; called by muse, mutect2
- CD93 | c.1222C>T p.H408Y | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV99849385; called by muse, mutect2, varscan2
- CD99 | c.487G>T p.E163* | Nonsense Mutation (SNP) | VAF 49/127 reads (39%) | catalogued as COSV101152315; called by muse, mutect2, varscan2
- CHD7 | c.1797G>C p.K599N | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.137); catalogued as COSV101418345; called by muse, mutect2, varscan2
- CYB561A3 | c.669G>T p.W223C | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99582542; called by muse, mutect2, varscan2
- CYB561A3 | c.494C>G p.S165C | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as COSV99582543; called by muse, mutect2, varscan2
- CYP4Z1 | c.128T>A p.L43Q | Missense Mutation (SNP) | VAF 69/138 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100497816, COSV61966984; called by muse, mutect2, varscan2
- DCHS1 | c.4978G>A p.E1660K | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100202310, COSV100202406, COSV55033920; called by muse, mutect2, varscan2
- DMD | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM0910024, COSV55854466, COSV55883347; called by muse, mutect2, varscan2
- DNAI3 | c.2278A>G p.I760V | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs775345447, COSV99642121; called by muse, mutect2, varscan2
- DSG4 | c.2164G>A p.G722R | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as COSV57389781; called by muse, mutect2, varscan2
- DST | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as rs767667427, COSV56812271; called by muse, mutect2, varscan2
- DXO | c.158C>G p.S53C | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100514784; called by muse, mutect2
- ERAL1 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.439); catalogued as COSV99650422; called by muse, varscan2
- FBXO41 | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.938); catalogued as rs375457673; called by muse, mutect2
- FKBP2 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV58588418; called by muse, mutect2, varscan2
- FSIP1 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.043); catalogued as rs766334823, COSV100618194; called by muse, mutect2, varscan2
- GBP2 | c.1174G>A p.D392N | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.071); catalogued as COSV100975411; called by muse, mutect2, varscan2
- GFOD1 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 54/86 reads (63%) | SIFT tolerated (0.16); PolyPhen benign (0.395); catalogued as COSV101014551; called by muse, mutect2, varscan2
- HLA-DQB1 | c.196C>T p.R66* | Nonsense Mutation (SNP) | VAF 26/110 reads (24%) | catalogued as rs200200868, COSV100891140, COSV66570496; called by muse, mutect2
- HYDIN | c.11650G>A p.E3884K | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated (0.51); PolyPhen benign (0.123); catalogued as rs774590218, COSV66637961; called by muse, mutect2, varscan2
- IKBKE | c.406A>G p.I136V | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV100898323, COSV100898336; called by muse, mutect2, varscan2
- INTS13 | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV99677492; called by muse, mutect2, varscan2
- ITGA8 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as rs775828839, COSV100959484; called by muse, mutect2, varscan2
- KIF5C | c.1592G>A p.R531K | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV101276172; called by muse, mutect2, varscan2
- KRT12 | c.789G>A p.M263I | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV99289044; called by muse, mutect2, varscan2
- LCMT2 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as rs1320742528, COSV59789944, COSV59791207; called by muse, mutect2, varscan2
- LRCH1 | c.1764+1G>T p.X588_splice | Splice Site (SNP) | VAF 22/49 reads (45%) | catalogued as COSV100243864; called by muse, mutect2, varscan2
- LYZL6 | c.164G>A p.S55N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1035869829; called by muse, mutect2
- MARCHF7 | c.1090C>G p.H364D | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as COSV99373921; called by muse, mutect2
- MARCHF7 | c.1526C>T p.S509L | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.977); catalogued as rs756972494, COSV99373924; called by muse, mutect2, varscan2
- MATR3 | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.956); catalogued as COSV100735268; called by muse, mutect2, varscan2
- MEGF6 | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.373); catalogued as rs762873581, COSV99620892; called by muse, mutect2, varscan2
- MMS22L | c.1580G>A p.G527D | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99247375; called by muse, mutect2, varscan2
- MPG | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1377338969, COSV99550014; called by muse, mutect2, varscan2
- MUC16 | c.20314T>C p.F6772L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV101200518; called by muse, mutect2, varscan2
- MUC17 | c.13138G>A p.E4380K | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV100074292, COSV60294909; called by muse, mutect2, varscan2
- NBEAL2 | c.3259C>T p.R1087C | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs1247894711, COSV99436752; called by muse, mutect2, varscan2
- NDST4 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 21/46 reads (46%) | catalogued as COSV52132973, COSV99997158; called by muse, mutect2, varscan2
- NEB | c.10075G>A p.E3359K | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.287); catalogued as COSV99425564; called by muse, mutect2, varscan2
- PADI6 | c.321C>G p.N107K | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV100639975; called by muse, mutect2, varscan2
- PAPOLB | c.1727C>T p.S576F | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as COSV101271535, COSV68199891; called by muse, mutect2, varscan2
- PARP10 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV100478163; called by muse, mutect2, varscan2
- PCDHB15 | c.1257C>G p.I419M | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV99179044; called by muse, mutect2, varscan2
- PCNX2 | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs765875758, COSV50789421; called by muse, mutect2, varscan2
- PEDS1 | c.622A>G p.I208V | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.699); catalogued as COSV100502110; called by muse, mutect2, varscan2
- PORCN | c.496G>A p.V166I | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs986541030, COSV58225807; called by muse, mutect2, varscan2
- PPP1CA | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.894); catalogued as rs746578350, COSV100335003; called by muse, varscan2
- PROM2 | c.416G>C p.R139P | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV100469207; called by muse, mutect2, varscan2
- PTPRD | c.4676G>A p.R1559Q | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1287979283, COSV100645160, COSV61975664; called by muse, mutect2, varscan2
- RAB11FIP4 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.902); catalogued as rs913536456, COSV57926560; called by muse, mutect2, varscan2
- RASGRP1 | c.2182G>A p.E728K | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.604); catalogued as COSV100172126; called by muse, mutect2, varscan2
- SAXO1 | c.346C>T p.R116* | Nonsense Mutation (SNP) | VAF 38/74 reads (51%) | catalogued as rs755473119, COSV101000182; called by muse, mutect2, varscan2
- SGO2 | c.2923C>T p.Q975* | Nonsense Mutation (SNP) | VAF 5/10 reads (50%) | catalogued as COSV100764733; called by muse, mutect2, varscan2
- SLC4A7 | c.779C>T p.S260F | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99840088; called by muse, mutect2, varscan2
- SLFN11 | c.1253C>G p.S418* | Nonsense Mutation (SNP) | VAF 7/18 reads (39%) | catalogued as COSV100390814; called by muse, mutect2, varscan2
- SMG1 | c.9714G>C p.Q3238H | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); catalogued as rs1012435107, COSV101246522; called by muse, mutect2, varscan2
- SPP1 | c.743G>A p.R248Q (on ENST00000395080 / NM_001040058.2; = p.R234Q on NM_000582.2) | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.52); PolyPhen benign (0.04); catalogued as rs377082687; called by muse, mutect2, varscan2
- SYTL1 | c.722C>T p.S241L (on ENST00000543823; = p.S229L on NM_032872.3) | Missense Mutation (SNP) | VAF 9/9 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs979432384, COSV100539451; called by muse, mutect2, varscan2
- TAF1 | c.3544G>C p.D1182H (on ENST00000373790 / NM_138923.4; = p.D1203H on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99336386; called by muse, mutect2, varscan2
- TELO2 | c.605C>G p.S202C | Missense Mutation (SNP) | VAF 55/186 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV99248544; called by muse, mutect2, varscan2
- TENM1 | c.6670G>A p.D2224N | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV64426944; called by muse, mutect2, varscan2
- TG | c.6299C>T p.S2100L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.175); catalogued as COSV99602123; called by muse, mutect2, varscan2
- TOPORS | c.2363G>A p.R788K | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0.158); catalogued as COSV100859552; called by muse, mutect2, varscan2
- TREM2 | c.586G>T p.A196S | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.081); catalogued as COSV100632654; called by muse, mutect2, varscan2
- TTC21B | c.3418G>A p.E1140K | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54630411, COSV99692570; called by muse, mutect2, varscan2
- TTLL13P | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.667); catalogued as rs774391359, COSV100296629; called by muse, mutect2, varscan2
- UBA6 | c.1705G>C p.D569H | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100451793; called by muse, mutect2, varscan2
- WWC3 | c.2280+1G>A p.X760_splice | Splice Site (SNP) | VAF 20/56 reads (36%) | catalogued as COSV66508963; called by muse, mutect2, varscan2
- YIPF1 | c.182_183del p.S61* | Frame Shift Del (DEL) | VAF 20/47 reads (43%) | catalogued as rs748448881; called by pindel, varscan2
- ZC3HAV1 | c.2274G>C p.K758N | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.156); catalogued as COSV99648869; called by muse, mutect2, varscan2
- ZC3HAV1 | c.565C>T p.R189W | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1159185212, COSV99648871; called by muse, mutect2, varscan2
- ZNF280C | c.1265C>T p.S422L | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100921255; called by muse, mutect2, varscan2
- ZSWIM8 | c.2012G>A p.G671D | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.313); catalogued as COSV101290049; called by muse, mutect2, varscan2
- ANGPTL7 | c.415_416del p.Y139Pfs*7 | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | called by mutect2, pindel, varscan2
- ATP6V0D2 | c.130+1del | Frame Shift Del (DEL) | VAF 12/24 reads (50%) | called by mutect2, pindel, varscan2
- IGHV3-49 | c.23T>G p.V8G | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- NIPBL | c.4269dup p.V1424Cfs*6 | Frame Shift Ins (INS) | VAF 18/67 reads (27%) | called by mutect2, pindel, varscan2
- PIP4K2B | c.1053G>A p.M351I | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RELN | c.3729_3743del p.A1244_P1248del | In Frame Del (DEL) | VAF 13/42 reads (31%) | called by mutect2, pindel, varscan2
- RIPK2 | c.1148_1160del p.M383Tfs*32 | Frame Shift Del (DEL) | VAF 15/59 reads (25%) | called by mutect2, pindel, varscan2
- XAGE2 | c.250G>A p.G84S | Missense Mutation (SNP) | VAF 206/461 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- AARS1 | c.2547C>T p.I849= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as rs746615745, COSV99933568; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADCY5 | c.3564G>A p.V1188= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as COSV100568500, COSV59194122; called by muse, mutect2, varscan2
- AIPL1 | c.150C>T p.D50= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs750387484, COSV100006145; called by muse, mutect2, varscan2
- ALKBH7 | c.78G>C p.L26= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV99831764; called by muse, varscan2
- ANKRD27 | c.1776G>A p.E592= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as rs1485360251, COSV100042995; called by muse, mutect2, varscan2
- CENPJ | c.3162G>A p.K1054= | Silent (SNP) | VAF 36/96 reads (38%) | catalogued as COSV101121547; called by muse, mutect2, varscan2
- CIAO3 | c.282G>A p.L94= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as rs368436484; called by muse, mutect2, varscan2
- DLGAP3 | c.195G>C p.L65= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as COSV99332935; called by muse, mutect2, varscan2
- ENDOD1 | c.195C>T p.F65= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV53588655; called by muse, mutect2, varscan2
- EPB42 | c.117C>T p.F39= (on ENST00000441366 / NM_001114134.2; = p.F69= on NM_000119.3) | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV100282065; called by muse, mutect2, varscan2
- FIP1L1 | c.1464G>A p.E488= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as COSV100184573; called by muse, mutect2, varscan2
- FLNA | c.5088G>A p.V1696= (on ENST00000369850 / NM_001110556.2; = p.V1688= on NM_001456.3) | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV100774927; called by muse, mutect2, varscan2
- GDPGP1 | c.972C>T p.D324= | Silent (SNP) | VAF 37/92 reads (40%) | catalogued as rs767364158, COSV100292110; called by muse, mutect2, varscan2
- GLIS2 | c.408C>T p.L136= | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as rs773863545, COSV52111385; called by muse, mutect2, varscan2
- HBB | c.57G>A p.V19= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as rs1554918177, COSV100092833; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- HEPH | c.2706C>T p.I902= (on ENST00000343002; = p.I635= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as COSV100295211; called by muse, mutect2, varscan2
- HYDIN | c.2580T>A p.P860= | Silent (SNP) | VAF 4/13 reads (31%) | called by mutect2, varscan2
- MSR1 | c.243G>A p.K81= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV100027375, COSV100027425; called by muse, mutect2, varscan2
- MUC2 | c.4089C>T p.F1363= | Silent (SNP) | VAF 45/106 reads (42%) | called by muse, mutect2, varscan2
- MYCBP2 | c.4935C>A p.L1645= (on ENST00000357337; = p.L1683= on NM_015057.5) | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV100631051, COSV62009798; called by muse, mutect2, varscan2
- NUP58 | c.918C>G p.L306= | Silent (SNP) | VAF 37/85 reads (44%) | catalogued as rs746912310, COSV101098842; called by muse, mutect2, varscan2
- NUP85 | c.168C>T p.I56= | Silent (SNP) | VAF 28/62 reads (45%) | catalogued as COSV55464576; called by muse, mutect2, varscan2
- PAX4 | c.783C>A p.G261= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100490230; called by muse, mutect2, varscan2
- POC1A | c.480C>T p.I160= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as rs753301992, COSV99624453; called by muse, mutect2, varscan2
- POU4F2 | c.456G>A p.S152= | Silent (SNP) | VAF 19/97 reads (20%) | catalogued as rs776534071, COSV99850686; called by muse, mutect2, varscan2
- RABGEF1 | c.99G>A p.K33= (on ENST00000439720 / NM_001287061.2; = p.K20= on NM_014504.3 and 29 other RefSeq transcripts) | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as COSV53160653; called by muse, mutect2, varscan2
- RASGRP2 | c.457C>T p.L153= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as rs1446862555, COSV100818300; called by muse, mutect2
- SLC18A2 | c.333C>T p.S111= | Silent (SNP) | VAF 30/33 reads (91%) | catalogued as rs780719336, COSV53693271; called by muse, mutect2, varscan2
- SLC2A4 | c.867C>T p.I289= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV99142765; called by muse, mutect2, varscan2
- SLC5A2 | c.807C>T p.P269= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV100393358, COSV57890968, COSV57891426; called by muse, mutect2, varscan2
- TFR2 | c.2046C>T p.I682= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as rs1221422629, COSV99774646; called by muse, mutect2, varscan2
- TNC | c.4635C>T p.F1545= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV100406044; called by muse, mutect2, varscan2
- TNIP3 | c.624A>G p.E208= | Silent (SNP) | VAF 5/107 reads (5%) | catalogued as COSV99284653; called by muse, mutect2
- TRPM2 | c.1200C>T p.V400= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as rs149400372; called by muse, mutect2, varscan2
- UBE2O | c.3795C>T p.F1265= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV100039461; called by muse, mutect2, varscan2
- UBE4A | c.880C>T p.L294= (on ENST00000252108 / NM_001204077.2; = p.L301= on NM_004788.4) | Silent (SNP) | VAF 31/40 reads (78%) | catalogued as COSV52804247; called by muse, mutect2, varscan2
- UNC79 | c.4980C>T p.S1660= (on ENST00000393151 / NM_001346218.2; = p.S1483= on NM_020818.5) | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs769147878, COSV99826555; called by muse, mutect2, varscan2
- WSCD2 | c.1287C>T p.F429= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV54583360, COSV99774915; called by muse, mutect2
- ZFHX4 | c.9714C>T p.V3238= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs370139182; called by muse, mutect2, varscan2
- C7orf66 | n.188A>G | RNA (SNP) | VAF 18/45 reads (40%) | catalogued as rs1201559359; called by muse, mutect2, varscan2
- GCNT2 | c.926-34797A>G | Intron (SNP) | VAF 22/41 reads (54%) | catalogued as rs774227743, COSV99399442; called by muse, mutect2, varscan2
- L1CAM | chrX:153886977 G>A | 5'Flank (SNP) | VAF 54/139 reads (39%) | called by muse, mutect2, varscan2
- SSX6P | n.182G>A | RNA (SNP) | VAF 135/264 reads (51%) | called by muse, mutect2, varscan2
- ZFP36L1 | chr14:68796089 C>T | 5'Flank (SNP) | VAF 9/16 reads (56%) | called by muse, mutect2, varscan2
